Somatic mutation profile of tumor specimen TCGA-D3-A1Q5-06A (aliquot TCGA-D3-A1Q5-06A-11D-A196-08) from TCGA case TCGA-D3-A1Q5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.5 years (24,638 days).
Specimen TCGA-D3-A1Q5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68562dd2-c372-444e-97ce-db3e890e2b64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q5-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q5-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40df9c92-0b06-4ec0-b51b-fff27c684fb3

The open-access MAF lists 431 somatic variants for this specimen: 289 protein-altering or splice-affecting, 131 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 131, Nonsense Mutation 16, Splice Region 6, RNA 5, Splice Site 4, Frame Shift Del 3, Translation Start Site 3, 5'Flank 2, Intron 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCC9 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV53987211; called by muse, mutect2, varscan2
- ABCF3 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53054766; called by muse, mutect2, varscan2
- ADAMTS18 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1353109719, COSV51423350; called by muse, mutect2, varscan2
- ADAMTS19 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV50735929, COSV99180420; called by muse, mutect2, varscan2
- AFAP1L2 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100412813, COSV58418853; called by muse, mutect2, varscan2
- AL121899.2 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV67352445; called by muse, mutect2, varscan2
- AL592490.1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV69427993; called by muse, mutect2, varscan2
- ALDH1L2 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51555020; called by muse, mutect2, varscan2
- AMER3 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV58470483; called by muse, mutect2, varscan2
- ANKMY2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV61011967; called by muse, mutect2, varscan2
- ANO7 | c.445C>T p.R149C (on ENST00000274979; = p.R94C on NM_001001666.4) | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs763945681, COSV51467841; called by muse, mutect2, varscan2
- AOC2 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV53200380; called by muse, mutect2, varscan2
- ARRDC5 | c.82G>A p.D28N (on ENST00000381781; = p.D14N on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as COSV67788335; called by muse, mutect2, varscan2
- ATP10D | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56713355; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1054G>T p.V352L (on ENST00000272238 / NM_001039362.2; = p.V306L on NM_144583.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV55351972, COSV55353868; called by muse, mutect2, varscan2
- BAZ2B | c.3602C>T p.A1201V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV54276937; called by muse, mutect2, varscan2
- BGN | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782393098, COSV59035776; called by muse, mutect2, varscan2
- BICD1 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV55688702; called by muse, mutect2, varscan2
- BMPR2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV65813612; called by muse, mutect2, varscan2
- BTAF1 | c.4577C>T p.P1526L | Missense Mutation (SNP) | VAF 74/84 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs925118820, COSV56439750; called by muse, mutect2, varscan2
- BTBD8 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV61547837; called by muse, mutect2
- C1QTNF3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV51469969; called by muse, mutect2, varscan2
- C1orf159 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1317676378, COSV53883919; called by muse, mutect2, varscan2
- C6orf89 | c.818G>T p.G273V (on ENST00000373685; = p.G280V on NM_152734.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62103322; called by muse, mutect2, varscan2
- CACNA2D1 | c.1660C>A p.Q554K (on ENST00000356253 / NM_001366867.1; = p.Q535K on NM_000722.4) | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as COSV62393110; called by muse, mutect2, varscan2
- CAMTA2 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61838457; called by muse, mutect2, varscan2
- CARD6 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs183781648, COSV54569236; called by muse, mutect2, varscan2
- CBLB | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV51437486, COSV51440591; called by muse, mutect2, varscan2
- CBX2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1555831034, COSV53970307; called by muse, mutect2, varscan2
- CCDC157 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV57842387; called by muse, mutect2, varscan2
- CCR10 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV52849601; called by muse, mutect2, varscan2
- CDCP1 | c.2082G>A p.K694= | Splice Region (SNP) | VAF 25/75 reads (33%) | catalogued as rs1444437435, COSV56108204; called by muse, mutect2, varscan2
- CDH2 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52296999; called by muse, varscan2
- CFAP53 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV68352914; called by muse, mutect2, varscan2
- CHAC1 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 43/188 reads (23%) | catalogued as rs1395822979, COSV71436270; called by muse, mutect2, varscan2
- CHODL | c.494G>A p.W165* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV54735432; called by muse, mutect2, varscan2
- CIB2 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1281648597, COSV51948655, COSV99363090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CKMT2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54175123; called by muse, mutect2, varscan2
- CNKSR1 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); catalogued as rs372873985, COSV64164283; called by muse, mutect2, varscan2
- CNTN5 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV54279105; called by muse, mutect2, varscan2
- COL11A1 | c.3278G>A p.G1093E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1477374848, COSV62198643; called by muse, mutect2, varscan2
- COL12A1 | c.2515G>A p.G839R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59408597; called by muse, mutect2, varscan2
- COL19A1 | c.1363G>C p.G455R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100505808, COSV59589366, COSV59590663; called by muse, mutect2
- COL19A1 | c.2623G>A p.G875R | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59589373; called by muse, mutect2, varscan2
- COL1A2 | c.4019C>T p.P1340L | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51966494; called by muse, mutect2, varscan2
- COL4A1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs927440520, COSV65432380; called by muse, mutect2, varscan2
- COL4A5 | c.3655C>T p.P1219S | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV60372687; called by muse, mutect2, varscan2
- CPM | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV58036249; called by muse, mutect2, varscan2
- CPN1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as rs1192584380, COSV100962696, COSV64942856; called by muse, mutect2, varscan2
- CPNE4 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70191493; called by muse, mutect2, varscan2
- CPT1C | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as rs754397461, COSV54922421; called by muse, mutect2, varscan2
- CPZ | c.968G>A p.R323Q (on ENST00000360986 / NM_001014447.3; = p.R312Q on NM_003652.3) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs538634471, COSV59921979; called by muse, mutect2, varscan2
- CROCC | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs756811015; called by muse, mutect2, varscan2
- CSF1R | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs370624765; called by muse, mutect2, varscan2
- CTNNB1 | c.1285T>G p.C429G | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62722155; called by muse, mutect2, varscan2
- CTNND2 | c.1900A>T p.N634Y | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58930110; called by muse, mutect2, varscan2
- CUBN | c.2743_2745del p.S915del | In Frame Del (DEL) | VAF 60/76 reads (79%) | catalogued as rs768809981; called by pindel, varscan2
- CWH43 | c.1863C>T p.I621= | Splice Region (SNP) | VAF 26/68 reads (38%) | catalogued as COSV56938041; called by muse, mutect2, varscan2
- CYB561 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.15); catalogued as COSV62540291; called by muse, mutect2, varscan2
- CYP3A4 | c.1556C>T p.P519L (on ENST00000336411; = p.P488L on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60504391; called by muse, mutect2, varscan2
- CYP4B1 | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54726364; called by muse, mutect2, varscan2
- DCDC2 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV51239813; called by muse, mutect2, varscan2
- DENND2C | c.1894C>T p.P632S (on ENST00000393274 / NM_001256404.2; = p.P575S on NM_198459.4) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67924169; called by muse, mutect2, varscan2
- DGCR2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs191822311, COSV54222596; called by muse, mutect2, varscan2
- DGKI | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761224295, COSV55969021, COSV55969848; called by muse, mutect2, varscan2
- DNAH5 | c.10024G>A p.E3342K | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV54219398; called by muse, mutect2, varscan2
- DNAH5 | c.7639C>A p.Q2547K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV54253647; called by muse, mutect2, varscan2
- DNAH5 | c.6041G>A p.G2014E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54247853, COSV54253659; called by muse, mutect2, varscan2
- DNAH6 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV52866601; called by muse, mutect2, varscan2
- DNAH8 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59477545; called by muse, mutect2
- DNAH9 | c.7085C>T p.P2362L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs767117314, COSV52377931; called by muse, mutect2, varscan2
- DNHD1 | c.12236T>A p.F4079Y | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV54443715; called by muse, mutect2, varscan2
- DOCK2 | c.1700C>A p.T567N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV56963580, COSV56989607; called by muse, mutect2, varscan2
- DPP9 | c.2018C>T p.A673V (on ENST00000598800; = p.A702V on NM_139159.5) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs988851117; called by muse, mutect2
- DPRX | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs148896232; called by muse, mutect2, varscan2
- DSC2 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV51869690; called by muse, mutect2, varscan2
- DSC3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV64575615; called by muse, mutect2, varscan2
- DYNAP | c.422C>T p.S141L (on ENST00000321600; = p.S115L on NM_173629.3) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs760155446, COSV58666818; called by muse, mutect2, varscan2
- DZIP1 | c.2269C>T p.R757C (on ENST00000347108; = p.R738C on NM_014934.5) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs746739193, COSV61263972; called by muse, mutect2, varscan2
- E2F3 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60899913; called by muse, mutect2, varscan2
- EDN1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761581288, COSV65080724, COSV65080801; called by muse, mutect2, varscan2
- ELN | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV52716056; called by muse, mutect2, varscan2
- ENOSF1 | c.631G>A p.D211N (on ENST00000340116 / NM_001354066.2; = p.D163N on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs762326635, COSV51895827; called by muse, mutect2, varscan2
- EPB42 | c.712G>A p.E238K (on ENST00000441366 / NM_001114134.2; = p.E268K on NM_000119.3) | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV55751818; called by muse, mutect2, varscan2
- EPHB2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV65867019; called by muse, mutect2, varscan2
- F8 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as CM034802, COSV64279001; called by muse, mutect2, varscan2
- FAT2 | c.5383G>A p.E1795K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV55815197, COSV55829946; called by muse, mutect2, varscan2
- FBN1 | c.6761G>A p.G2254E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57325859; called by muse, mutect2, varscan2
- FLNC | c.2515G>A p.G839S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768813870, COSV57965471; called by muse, mutect2, varscan2
- FMO2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV52950525; called by muse, mutect2, varscan2
- FOXN1 | c.494T>G p.V165G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV56884398; called by muse, mutect2, varscan2
- FRRS1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV54924482; called by muse, mutect2, varscan2
- FUT9 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as COSV56157559; called by muse, mutect2, varscan2
- GABRA1 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV50120172; called by muse, mutect2, varscan2
- GABRA6 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50892822; called by muse, mutect2, varscan2
- GABRG2 | c.1267C>A p.R423S (on ENST00000361925 / NM_001375343.1; = p.R383S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV62716095, COSV62717375, COSV62718640; called by muse, mutect2, varscan2
- GAS2L1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs1342365374; called by muse, mutect2, varscan2
- GCN1 | c.2983C>T p.H995Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV56115161; called by muse, mutect2, varscan2
- GDF6 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.745); catalogued as COSV54627986; called by muse, mutect2, varscan2
- GGT5 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.893); catalogued as COSV54072634; called by muse, mutect2
- GIMAP1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.401); catalogued as COSV56189870; called by muse, mutect2, varscan2
- GPRC5D | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57433495; called by muse, mutect2, varscan2
- GRIA2 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52407027; called by muse, mutect2, varscan2
- GRIK4 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV70807441; called by muse, mutect2, varscan2
- GRM3 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV64469402; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2230G>A p.E744K (on ENST00000265755 / NM_016328.3; = p.E729K on NM_005685.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1554358182, COSV56085083; called by muse, mutect2, varscan2
- GTF3C1 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62245118; called by muse, mutect2, varscan2
- H2AX | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV53830203; called by muse, mutect2, varscan2
- HECW2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV53670855; called by muse, mutect2, varscan2
- HEPACAM2 | c.587C>T p.S196F (on ENST00000394468 / NM_001039372.4; = p.S184F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.582); catalogued as COSV59063373; called by muse, mutect2, varscan2
- HERC2 | c.9953C>T p.S3318L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260050907, COSV55351389, COSV99875773; called by muse, mutect2, varscan2
- HIBADH | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 119/618 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55317224; called by muse, mutect2, varscan2
- HIPK1 | c.887T>G p.L296W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65786800; called by muse, mutect2, varscan2
- IFIH1 | c.2805C>T p.F935= | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as COSV55130393; called by muse, mutect2, varscan2
- IGLV11-55 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs368002354, COSV66504586; called by muse, mutect2, varscan2
- ITGAX | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as COSV51651878; called by muse, mutect2, varscan2
- ITIH3 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56578908; called by muse, mutect2, varscan2
- ITPRID1 | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV60072494, COSV60072933; called by muse, mutect2, varscan2
- ITPRID2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192229678, COSV57471033; called by muse, mutect2, varscan2
- KCNH7 | c.1463T>G p.I488R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59803362, COSV59814483; called by muse, mutect2, varscan2
- KDM5B | c.3658C>T p.H1220Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52510345; called by muse, mutect2, varscan2
- KDM6B | c.4318A>G p.I1440V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.127); catalogued as COSV54687497; called by muse, mutect2, varscan2
- KMT2D | c.14458C>T p.P4820S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV56488917; called by muse, mutect2, varscan2
- KMT2D | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV56488944; called by muse, mutect2, varscan2
- KNTC1 | c.4871C>T p.S1624L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs763188648, COSV61081740, COSV61082253; called by muse, mutect2, varscan2
- KRTAP19-7 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.766); catalogued as COSV58366641; called by muse, mutect2, varscan2
- KRTAP26-1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62128847; called by muse, mutect2, varscan2
- LAMA2 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762781837, COSV70355646; called by mutect2, varscan2
- LAMC2 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51459942, COSV51459977; called by muse, mutect2, varscan2
- LCE5A | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.964); catalogued as COSV57500889, COSV57501643; called by muse, mutect2, varscan2
- LCN8 | c.268G>A p.D90N (on ENST00000612714 / NM_001345934.1; = p.D67N on NM_178469.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs369638208; called by muse, mutect2, varscan2
- LCTL | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV58423135; called by muse, mutect2, varscan2
- LGR6 | c.2549C>T p.P850L (on ENST00000367278 / NM_001017403.1; = p.P798L on NM_021636.3) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV55166852; called by muse, mutect2, varscan2
- LOXL2 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV66693686; called by muse, mutect2, varscan2
- LPO | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779010556, COSV51862765; called by muse, mutect2, varscan2
- LRRC37A3 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs1398414899, COSV59764390; called by muse, mutect2, varscan2
- LRRC49 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767675160, COSV53015767; called by muse, mutect2, varscan2
- LRRCC1 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as rs768772031, COSV64485438; called by muse, mutect2, varscan2
- LRRN2 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV65784762; called by muse, mutect2, varscan2
- LTBP2 | c.4204G>A p.G1402R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV56214466; called by muse, mutect2, varscan2
- LTBP2 | c.1361A>G p.K454R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56206739; called by muse, mutect2, varscan2
- MECOM | c.1912G>A p.D638N (on ENST00000468789 / NM_001105078.4; = p.D826N on NM_004991.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52975672; called by muse, mutect2, varscan2
- MEX3B | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV61664089; called by muse, mutect2
- MICAL2 | c.5016C>G p.F1672L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.062); catalogued as COSV56288811; called by muse, mutect2, varscan2
- MINK1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61793653; called by muse, mutect2, varscan2
- MPP1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 100/112 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65728919; called by muse, mutect2, varscan2
- MRPS18A | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV64522310; called by muse, varscan2
- MUC16 | c.29675C>A p.T9892K | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV67495661; called by muse, mutect2, varscan2
- MUC16 | c.25982C>T p.S8661F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.048); catalogued as rs866918936, COSV67495666; called by muse, mutect2, varscan2
- MUC16 | c.6799C>T p.P2267S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67456280; called by muse, mutect2, varscan2
- MUC16 | c.5666G>A p.G1889E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV67483032; called by muse, mutect2, varscan2
- MUC16 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.096); catalogued as COSV67495683; called by muse, mutect2, varscan2
- MYH6 | c.4103C>T p.S1368L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs778374207, COSV62454706; called by muse, mutect2, varscan2
- MYH6 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs759945266, COSV62454711; called by muse, mutect2, varscan2
- MYO1F | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV57800427; called by muse, mutect2, varscan2
- MYO3A | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56350477; called by muse, mutect2, varscan2
- NCOR2 | c.6280G>A p.G2094S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs763944351, COSV62304827; called by muse, mutect2, varscan2
- NDST4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs148107560, COSV52130897, COSV52131750; called by muse, mutect2, varscan2
- NLGN3 | c.2510C>T p.T837I (on ENST00000358741 / NM_181303.2; = p.T817I on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as rs778287494, COSV62445403; called by muse, varscan2
- NONO | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV52135662; called by muse, mutect2, varscan2
- NONO | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52140525; called by muse, mutect2, varscan2
- NOTCH1 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53097045; called by muse, mutect2, varscan2
- NPTN | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54740211; called by muse, mutect2, varscan2
- NPY | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54216106; called by muse, mutect2, varscan2
- NR5A2 | c.1316G>A p.R439H (on ENST00000367362 / NM_205860.3; = p.R393H on NM_003822.5) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.112); catalogued as rs1182541887, COSV52648273, COSV52648662; called by muse, mutect2, varscan2
- NRIP1 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59660521; called by muse, mutect2, varscan2
- NRXN3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV73586398; called by muse, mutect2
- NSMCE3 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.679); catalogued as COSV54289176; called by muse, mutect2, varscan2
- OBI1 | c.1366T>G p.S456A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV56147645; called by muse, mutect2, varscan2
- OR10AG1 | c.309T>A p.C103* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV56634977; called by muse, mutect2, varscan2
- OR1M1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.123); catalogued as COSV70036965; called by muse, mutect2, varscan2
- OR2C1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59241425; called by muse, mutect2, varscan2
- OR2G2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV60742389; called by muse, mutect2, varscan2
- OR2H1 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV65810526, COSV65811487; called by muse, mutect2, varscan2
- OR4S1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369830806, COSV60679044, COSV60679094; called by muse, mutect2, varscan2
- OR51A4 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66749179, COSV66750110; called by muse, mutect2, varscan2
- OR51G2 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV58995206; called by muse, mutect2, varscan2
- OR6A2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60265921; called by muse, mutect2, varscan2
- OR6K2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV62743558, COSV62744278; called by muse, mutect2, varscan2
- OTOF | c.2626G>A p.E876K (on ENST00000272371 / NM_194248.3; = p.E129K on NM_004802.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV55520854; called by muse, mutect2, varscan2
- PADI4 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV64925187; called by muse, mutect2, varscan2
- PARP12 | c.1923G>T p.E641D | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV54937341; called by muse, mutect2, varscan2
- PCDH11Y | c.3302G>A p.G1101E | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.98); catalogued as COSV53092065; called by mutect2, varscan2
- PCDHA13 | c.2271G>T p.R757S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV56547870; called by muse, mutect2, varscan2
- PCDHB15 | c.1916G>A p.R639K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); catalogued as COSV51425088; called by muse, mutect2, varscan2
- PCDHB3 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs1554272573, COSV50635812; called by muse, mutect2, varscan2
- PDZD2 | c.5119G>A p.E1707K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.08); catalogued as COSV56851190; called by muse, mutect2, varscan2
- PKDREJ | c.2240G>T p.S747I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV53553399; called by muse, varscan2
- PKP4 | c.1560C>T p.P520= | Splice Region (SNP) | VAF 32/86 reads (37%) | catalogued as COSV67679627; called by muse, mutect2, varscan2
- PLA2G4E | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1566837132, COSV68152495; called by muse, mutect2, varscan2
- PLVAP | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV53087904; called by muse, mutect2, varscan2
- PLXNA4 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs372771390; called by muse, mutect2, varscan2
- POLR2B | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58902946; called by muse, mutect2, varscan2
- POT1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV62934999; called by muse, mutect2, varscan2
- PRPF6 | c.2170A>G p.M724V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53879070; called by muse, mutect2, varscan2
- PRSS23 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54707737; called by muse, mutect2, varscan2
- RAB25 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs201881638, COSV63108827; called by muse, mutect2, varscan2
- RANBP10 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV58161535; called by muse, mutect2, varscan2
- RASGEF1C | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV63184855; called by muse, mutect2, varscan2
- RFXANK | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs1481038979, COSV57393933; called by muse, mutect2, varscan2
- RIMBP2 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769627450, COSV55472916; called by muse, mutect2, varscan2
- RNF148 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57387250; called by muse, mutect2
- RNGTT | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.495); catalogued as rs761305080, COSV55660904; called by muse, mutect2, varscan2
- RPTN | c.1038G>A p.M346I | Missense Mutation (SNP) | VAF 358/567 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV60169326; called by muse, mutect2, varscan2
- RRBP1 | c.3485C>T p.A1162V (on ENST00000377813 / NM_001365613.2; = p.A729V on NM_004587.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV55709198; called by muse, mutect2, varscan2
- RS1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.073); catalogued as COSV66107564; called by muse, mutect2, varscan2
- RS1 | c.79-1G>A p.X27_splice | Splice Site (SNP) | VAF 20/47 reads (43%) | catalogued as COSV101183856; called by muse, mutect2, varscan2
- RSPH10B2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99786409; called by mutect2, varscan2
- RYR1 | c.8603C>T p.S2868F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV62111473; called by muse, mutect2
- RYR2 | c.13231C>T p.P4411S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV63710735; called by muse, mutect2
- SAMD9 | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 27/164 reads (16%) | catalogued as rs763070754, COSV66077326; called by muse, mutect2, varscan2
- SCAF4 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV54592586; called by muse, mutect2
- SCARF1 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs768864542, COSV53961519; called by muse, mutect2, varscan2
- SCG3 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.076); catalogued as COSV55023371; called by muse, mutect2, varscan2
- SCN10A | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs866716316, COSV71860652; called by muse, mutect2, varscan2
- SCN11A | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56578839; called by muse, mutect2, varscan2
- SEC16B | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV57624910; called by muse, mutect2, varscan2
- SEC31A | c.3319A>T p.I1107F (on ENST00000355196 / NM_001318120.1; = p.I1068F on NM_016211.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52352147; called by muse, mutect2, varscan2
- SERPINA3 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs375245228; called by muse, mutect2, varscan2
- SGSM1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68513896; called by muse, mutect2, varscan2
- SHANK2 | c.2474C>G p.T825R | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.605); catalogued as rs782271440, COSV53608120, COSV53620072; called by muse, mutect2, varscan2
- SI | c.2026G>T p.G676W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52302014; called by muse, mutect2, varscan2
- SIGLECL1 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as rs866540825, COSV57064799; called by muse, mutect2, varscan2
- SIRPB1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV53540876; called by muse, mutect2, varscan2
- SLC15A1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772787952, COSV64733798; called by muse, mutect2, varscan2
- SLC15A1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as rs758384867, COSV64711879; called by muse, mutect2, varscan2
- SLC16A1 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs763573918, COSV63708894; called by muse, mutect2, varscan2
- SLC25A35 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs747500240, COSV56840294, COSV99873983; called by muse, mutect2, varscan2
- SLC29A2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.18); PolyPhen benign (0.417); catalogued as COSV60804233; called by muse, mutect2, varscan2
- SLC37A3 | c.1025-1G>A p.X342_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV58268887; called by muse, mutect2, varscan2
- SLC6A15 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57024096; called by muse, mutect2, varscan2
- SLCO1B1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs138965366; called by muse, mutect2, varscan2
- SNTG1 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs549965322, COSV52474468; called by muse, mutect2, varscan2
- SPG11 | c.6274G>A p.D2092N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56002452; called by muse, mutect2, varscan2
- SPHKAP | c.1331G>A p.W444* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV60879489; called by muse, mutect2, varscan2
- SPOCK1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.805); catalogued as rs200097317, COSV56467475; called by muse, mutect2, varscan2
- STAB2 | c.6565G>A p.D2189N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752695393, COSV66347583; called by muse, mutect2, varscan2
- STAC | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs867013407, COSV56218639; called by muse, mutect2
- STK32A | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60423420; called by muse, mutect2, varscan2
- STX5 | c.424-1G>A p.X142_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as COSV53682081; called by muse, mutect2, varscan2
- STXBP4 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 106/357 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1419910385, COSV54841366; called by muse, mutect2, varscan2
- SYMPK | c.2848C>G p.H950D | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55616009; called by muse, mutect2, varscan2
- TIMELESS | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.659); catalogued as rs1251524473, COSV57515445; called by muse, mutect2, varscan2
- TM9SF4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1465164966, COSV54111746; called by muse, mutect2, varscan2
- TMEM132E | c.1169C>T p.S390F (on ENST00000321639; = p.S480F on NM_001304438.2) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV58695194, COSV58700681; called by muse, mutect2, varscan2
- TMTC3 | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57126456; called by muse, mutect2, varscan2
- TNN | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV53436206; called by muse, mutect2, varscan2
- TOP2B | c.199C>T p.R67C (on ENST00000264331 / NM_001330700.2; = p.R62C on NM_001068.3) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51968957; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2, varscan2
- TRIM42 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs753214955, COSV53883156, COSV53886066; called by muse, mutect2
- TRIM42 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53887088; called by muse, mutect2, varscan2
- TRIOBP | c.4745G>A p.W1582* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV60381647, COSV60384692; called by muse, mutect2, varscan2
- TRMU | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV51989994, COSV51991642; called by muse, mutect2, varscan2
- TRPC5 | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as COSV53303475; called by muse, mutect2, varscan2
- TTN | c.33797C>T p.P11266L (on ENST00000591111; = p.P10339L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/170 reads (88%) | PolyPhen benign (0); catalogued as COSV60363421; called by muse, mutect2, varscan2
- TTN | c.17477G>A p.G5826E (on ENST00000591111; = p.G4899E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/37 reads (89%) | PolyPhen probably damaging (1); catalogued as COSV60363432; called by muse, mutect2, varscan2
- ULK2 | c.652A>G p.S218G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV64448706; called by muse, mutect2, varscan2
- UTRN | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62348726; called by muse, mutect2, varscan2
- VAV1 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58385554; called by muse, mutect2, varscan2
- VSIG10 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs1242811875, COSV63654495; called by muse, mutect2, varscan2
- VSX1 | c.627+1G>A p.X209_splice | Splice Site (SNP) | VAF 42/178 reads (24%) | catalogued as COSV65022136; called by muse, mutect2, varscan2
- WDR6 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV58247616; called by muse, mutect2, varscan2
- ZC3H7B | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV60960783; called by muse, mutect2, varscan2
- ZFHX4 | c.8753C>T p.P2918L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV51497510; called by muse, mutect2, varscan2
- ZFP3 | c.762A>T p.E254D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV59584301; called by muse, mutect2, varscan2
- ZNF135 | c.1345C>T p.H449Y (on ENST00000313434 / NM_001289401.2; = p.H461Y on NM_003436.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.055); catalogued as COSV57886112; called by muse, mutect2, varscan2
- ZNF254 | c.1868T>C p.I623T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV61644991; called by muse, mutect2, varscan2
- ZNF256 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV56598839, COSV56599872; called by muse, mutect2, varscan2
- ZNF443 | c.1848T>G p.Y616* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV56894465; called by muse, mutect2, varscan2
- ZNF48 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV60784391; called by muse, mutect2, varscan2
- ZNF534 | c.913C>T p.H305Y (on ENST00000332323 / NM_001143939.3; = p.H292Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs267605633, COSV56514865; called by muse, mutect2, varscan2
- ZNF548 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.92); catalogued as COSV60242050; called by muse, mutect2, varscan2
- ZNF556 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs367809549; called by muse, mutect2, varscan2
- ZNF667 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs149168669, COSV99410899; called by muse, mutect2, varscan2
- ZNF823 | c.1328C>T p.P443L (on ENST00000341191 / NM_001297610.2; = p.P399L on NM_017507.2) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1273351738, COSV57876463; called by muse, mutect2, varscan2
- CNTNAP3 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL25A1 | c.1665T>G p.D555E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); called by muse, mutect2
- EXO5 | c.112_113del p.K38Gfs*4 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- HOXA13 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.52G>A | Splice Region (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- KATNAL2 | c.1267C>T p.P423S (on ENST00000356157 / NM_001353899.1; = p.P351S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTCL1 | c.4082C>T p.P1361L (on ENST00000306329 / NM_001378206.1; = p.P1042L on NM_015210.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NPC1L1 | c.2846C>T p.P949L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- OBSCN | c.6862C>T p.L2288= | Splice Region (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- POTEA | c.1121C>T p.P374L (on ENST00000519951 / NM_001005365.2; = p.P328L on NM_001002920.1) | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TMEM14B | c.122_140del p.A41Vfs*2 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- USH2A | c.2392_2402del p.D798Ifs*8 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- ZNF207 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA13 | c.13416C>T p.S4472= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs374213390; called by muse, mutect2, varscan2
- ADGRD1 | c.1137C>T p.A379= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV55458190; called by muse, mutect2, varscan2
- ASTN1 | c.2832C>T p.P944= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs1376082472, COSV62507281; called by muse, mutect2
- ATP2B3 | c.414G>A p.G138= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV54862411, COSV99684738; called by muse, mutect2, varscan2
- ATP6V0E1 | c.216C>T p.T72= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1448885632, COSV54186233; called by muse, mutect2, varscan2
- C1orf127 | c.1398C>T p.P466= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV65439088; called by muse, mutect2, varscan2
- CACNA1B | c.1038C>T p.F346= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs1332157167, COSV53127082, COSV53150083; called by muse, mutect2, varscan2
- CCBE1 | c.861C>T p.P287= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV67951623; called by muse, mutect2, varscan2
- CCNE1 | c.1134C>T p.A378= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV52905865; called by muse, mutect2, varscan2
- CENPJ | c.48C>T p.F16= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV67884309; called by muse, mutect2, varscan2
- CLEC10A | c.666G>A p.R222= (on ENST00000254868 / NM_182906.4; = p.R198= on NM_006344.4) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV54701224; called by muse, mutect2, varscan2
- CNTNAP1 | c.2550C>T p.F850= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs756084575, COSV52850086; called by muse, mutect2, varscan2
- CROCC | c.2559C>T p.A853= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- CSMD2 | c.4834C>A p.R1612= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV53965990; called by muse, varscan2
- CUL5 | c.1674A>T p.V558= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV67610298; called by muse, mutect2, varscan2
- DDR1 | c.1815C>T p.F605= (on ENST00000324771; = p.F568= on NM_001954.4) | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV61321355; called by muse, mutect2, varscan2
- DLG2 | c.1872G>A p.S624= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs369253300, COSV54645502; called by muse, mutect2, varscan2
- DNAH1 | c.1923C>T p.V641= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV70236642; called by muse, mutect2, varscan2
- DNAH2 | c.7755G>A p.G2585= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV66727720; called by muse, mutect2, varscan2
- DTX2 | c.1059C>T p.S353= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV56865378; called by muse, mutect2
- EMILIN1 | c.648G>A p.T216= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1448403629, COSV53154854, COSV53157019; called by muse, mutect2, varscan2
- ENPP1 | c.2082C>T p.S694= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV62936562; called by muse, mutect2, varscan2
- EPB41L1 | c.2241C>T p.I747= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52445364; called by muse, mutect2, varscan2
- EPN2 | c.192G>A p.L64= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV59063665; called by muse, mutect2, varscan2
- FAM111B | c.1062C>T p.P354= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV59113749; called by muse, mutect2, varscan2
- FAT4 | c.189C>G p.T63= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV67900939; called by muse, mutect2, varscan2
- FCN2 | c.846G>A p.G282= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs907116410, COSV52477415, COSV52478823; called by muse, mutect2, varscan2
- FERMT1 | c.63C>A p.P21= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54097637; called by muse, mutect2, varscan2
- FGD2 | c.1086C>T p.F362= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1215023542, COSV51463148; called by muse, mutect2
- GABRA6 | c.774C>T p.S258= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV50879498; called by muse, mutect2, varscan2
- GAS2L1 | c.516C>T p.P172= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- GDF10 | c.738C>A p.V246= | Silent (SNP) | VAF 44/56 reads (79%) | called by muse, varscan2
- GJC2 | c.66C>T p.F22= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV64512672; called by muse, mutect2, varscan2
- GPAT3 | c.1189C>T p.L397= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV52359868; called by muse, mutect2, varscan2
- GPR101 | c.660G>A p.R220= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV53239112; called by muse, mutect2, varscan2
- GPRC5D | c.198C>T p.F66= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV57432967; called by muse, mutect2, varscan2
- GRID2 | c.939G>A p.K313= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV56270352, COSV99937482; called by muse, mutect2, varscan2
- HIF3A | c.1810C>T p.L604= (on ENST00000377670 / NM_152795.4; = p.L535= on NM_022462.4) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV52204890; called by muse, mutect2, varscan2
- HMCN1 | c.4170C>T p.P1390= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV54943701; called by muse, mutect2, varscan2
- ICAM1 | c.678C>T p.V226= | Silent (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- ICAM1 | c.679C>T p.L227= | Silent (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- IDUA | c.813C>T p.S271= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs569215528, COSV56106667; called by muse, mutect2
- IGDCC3 | c.2286G>A p.G762= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs904272197; called by muse, mutect2, varscan2
- IGHG4 | c.636C>T p.I212= | Silent (SNP) | VAF 69/310 reads (22%) | catalogued as rs773839436; called by muse, mutect2, varscan2
- IL16 | c.1269G>A p.T423= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as rs746045639, COSV57268437; called by muse, mutect2, varscan2
- IMPA2 | c.501G>A p.K167= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV52321691; called by muse, mutect2, varscan2
- INMT | c.507C>T p.A169= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs1562833490, COSV50002783; called by muse, mutect2, varscan2
- IRAG1 | c.2688G>A p.R896= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV70213101; called by muse, mutect2, varscan2
- KATNAL2 | c.1266C>T p.L422= (on ENST00000356157 / NM_001353899.1; = p.L350= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1180607215, COSV55301993; called by muse, mutect2, varscan2
- KCNH5 | c.1734C>T p.Y578= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV59778978; called by muse, mutect2, varscan2
- KCNK1 | c.846G>A p.V282= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV64036642; called by muse, mutect2, varscan2
- KCNN2 | c.717C>T p.A239= (on ENST00000264773; = p.A451= on NM_021614.4) | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as COSV53299586; called by muse, mutect2, varscan2
- KLHDC7A | c.495G>A p.P165= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs769337343, COSV101272800, COSV68771102; called by muse, mutect2, varscan2
- KRT9 | c.1071C>T p.S357= | Silent (SNP) | VAF 161/292 reads (55%) | catalogued as COSV55852867; called by muse, mutect2, varscan2
- LAMB3 | c.480C>T p.V160= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV61919952; called by muse, mutect2, varscan2
- LHX8 | c.498C>T p.S166= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs1280817231, COSV53960292; called by muse, mutect2, varscan2
- LMX1A | c.303C>T p.I101= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs757812169, COSV54228679, COSV99673041; called by muse, mutect2, varscan2
- LPCAT4 | c.396C>T p.F132= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs775927004, COSV59215939; called by muse, mutect2, varscan2
- LTBP2 | c.2140C>T p.L714= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV56204257; called by muse, mutect2, varscan2
- MAMDC4 | c.1125G>A p.R375= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs771811709; called by muse, mutect2, varscan2
- MARCHF7 | c.990A>G p.V330= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV52031640; called by muse, mutect2, varscan2
- MISP | c.933G>A p.R311= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs760919840, COSV53121053; called by muse, mutect2, varscan2
- MLH3 | c.2682T>C p.S894= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV53159332; called by muse, mutect2, varscan2
- MORC1 | c.2649G>A p.R883= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV51723817; called by muse, mutect2, varscan2
- MTG2 | c.678C>T p.H226= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs769111941, COSV63694921; called by muse, mutect2, varscan2
- MUC16 | c.41295G>A p.G13765= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs866520286, COSV66693100; called by muse, mutect2, varscan2
- MUC16 | c.40597C>T p.L13533= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV66696849; called by muse, mutect2, varscan2
- MUC16 | c.22995C>T p.S7665= | Silent (SNP) | VAF 39/61 reads (64%) | catalogued as COSV67495672; called by muse, mutect2, varscan2
- MYCT1 | c.87C>T p.F29= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs568217820, COSV65890898; called by muse, mutect2, varscan2
- MYOM3 | c.2124C>T p.L708= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV58401327; called by muse, mutect2, varscan2
- NDN | c.936C>T p.H312= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs1167901621, COSV59361554; called by muse, mutect2, varscan2
- NECTIN2 | c.1014C>T p.G338= | Silent (SNP) | VAF 62/344 reads (18%) | catalogued as COSV52980276; called by muse, varscan2
- NLRP3 | c.2256G>A p.G752= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as rs1298770385, COSV60221127; called by muse, mutect2, varscan2
- NLRP9 | c.1896C>T p.F632= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs776205549, COSV60468009; called by muse, mutect2, varscan2
- NRSN1 | c.270C>T p.I90= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs770598939, COSV65893738; called by muse, mutect2, varscan2
- NXNL1 | c.249G>A p.T83= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs374141772, COSV57325286; called by muse, mutect2, varscan2
- OR10G9 | c.768C>T p.F256= | Silent (SNP) | VAF 51/58 reads (88%) | catalogued as COSV66685830; called by muse, mutect2, varscan2
- OR2A5 | c.663C>T p.I221= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as COSV68738601; called by muse, mutect2, varscan2
- OR2C3 | c.822C>T p.F274= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs200844035, COSV63575677, COSV63576441; called by muse, mutect2, varscan2
- OR2T12 | c.516C>T p.I172= | Silent (SNP) | VAF 50/82 reads (61%) | catalogued as rs1186607809, COSV58777432, COSV58778756; called by muse, mutect2, varscan2
- OR2T29 | c.88C>T p.L30= | Silent (SNP) | VAF 35/54 reads (65%) | called by muse, mutect2, varscan2
- OR6K2 | c.738C>T p.F246= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV62744274; called by muse, mutect2, varscan2
- OR8H2 | c.468C>A p.S156= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV57944255, COSV57947549; called by muse, mutect2, varscan2
- OR9Q2 | c.174G>A p.P58= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as rs61902822, COSV61112704; called by muse, mutect2, varscan2
- PAX1 | c.1347C>T p.S449= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1289988985, COSV68272407; called by muse, mutect2
- PAX5 | c.771G>A p.K257= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100814653, COSV63909770; called by muse, mutect2, varscan2
- PCDHGA10 | c.132G>A p.E44= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV54038336; called by muse, mutect2, varscan2
- PDZD8 | c.3189G>A p.E1063= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV53693786; called by muse, mutect2, varscan2
- PKDREJ | c.2289C>A p.T763= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs867543195, COSV53553386; called by muse, varscan2
- POLR3A | c.2256C>T p.I752= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV64932162; called by muse, mutect2
- POT1 | c.306A>T p.A102= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV62934984; called by muse, mutect2, varscan2
- PRAMEF2 | c.840C>T p.F280= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs761807266, COSV53577804; called by muse, mutect2, varscan2
- PRDM10 | c.2451C>T p.P817= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV58805459; called by muse, mutect2, varscan2
- PXDN | c.3819C>T p.I1273= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV53236829, COSV53246677; called by muse, mutect2, varscan2
- PYGB | c.1437G>A p.K479= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV53823035; called by muse, mutect2, varscan2
- RAB27B | c.63G>A p.G21= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs776288046, COSV50496483; called by muse, mutect2, varscan2
- RARRES2 | c.159G>A p.E53= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs373387224; called by mutect2, varscan2
- RBM47 | c.657C>T p.I219= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1232131370, COSV55943768; called by muse, mutect2, varscan2
- REST | c.444G>A p.E148= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV58361650; called by muse, mutect2, varscan2
- RGS14 | c.1698C>T p.L566= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs1561619679, COSV68772049; called by muse, mutect2, varscan2
- RPS14 | c.291C>T p.L97= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs1161910922, COSV56316538; called by muse, mutect2, varscan2
- RRP1 | c.210C>T p.L70= | Silent (SNP) | VAF 29/32 reads (91%) | catalogued as COSV71856965; called by muse, mutect2, varscan2
- RTP1 | c.141G>A p.K47= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs141573394; called by muse, mutect2, varscan2
- RYR3 | c.10956C>T p.I3652= (on ENST00000389232; = p.I3653= on NM_001036.6) | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs367892350; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCFD1 | c.408A>T p.A136= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV61727575; called by muse, mutect2, varscan2
- SCN3A | c.3882C>T p.Y1294= | Silent (SNP) | VAF 37/43 reads (86%) | catalogued as COSV51825295; called by muse, mutect2, varscan2
- SCTR | c.618C>T p.T206= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as rs1384949375, COSV50032408; called by muse, mutect2, varscan2
- SCUBE1 | c.138C>T p.I46= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs755600943, COSV51809006; called by muse, mutect2, varscan2
- SEMA5B | c.3157C>T p.L1053= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV52108606; called by muse, mutect2, varscan2
- SEZ6L | c.1080C>T p.I360= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV50661727; called by muse, mutect2, varscan2
- SH3TC2 | c.1992A>G p.G664= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs1380437828, COSV60467955; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC26A7 | c.1542G>A p.L514= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV52604443; called by muse, mutect2, varscan2
- SLC47A1 | c.165C>T p.I55= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV54504319; called by muse, mutect2, varscan2
- SLC7A11 | c.1368C>T p.I456= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV54933842; called by muse, mutect2, varscan2
- SLC9A3 | c.1677C>T p.I559= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs368563869, COSV53805078; called by muse, mutect2, varscan2
- STAB2 | c.2694G>A p.Q898= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs1447880456, COSV66339753, COSV66347576; called by muse, mutect2, varscan2
- STK31 | c.1581C>T p.F527= | Silent (SNP) | VAF 43/62 reads (69%) | catalogued as COSV63456041; called by muse, mutect2, varscan2
- SYCP2L | c.2367G>A p.G789= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1388110623, COSV51656827; called by muse, mutect2, varscan2
- TENM2 | c.1092G>A p.L364= (on ENST00000518659 / NM_001122679.2; = p.L173= on NM_001080428.3) | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs747399401, COSV69135949; called by muse, mutect2, varscan2
- THSD4 | c.42C>T p.F14= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV55980279; called by muse, mutect2, varscan2
- TIE1 | c.633C>T p.I211= | Silent (SNP) | VAF 47/73 reads (64%) | catalogued as rs757103161, COSV65248488, COSV65248942; called by muse, mutect2, varscan2
- TKTL2 | c.168G>A p.T56= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs776271739, COSV54917421, COSV99761399; called by muse, mutect2, varscan2
- TLN2 | c.7296C>T p.V2432= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs202049914; called by muse, mutect2
- TPO | c.189G>A p.K63= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61102285; called by muse, mutect2, varscan2
- TRIM42 | c.1626C>T p.F542= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV53887100; called by muse, mutect2, varscan2
- TRIO | c.7545C>T p.R2515= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV59992553; called by muse, mutect2, varscan2
- UCMA | c.165G>A p.S55= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs770156385, COSV66321509, COSV66322012; called by muse, mutect2, varscan2
- ZNF229 | c.1182C>T p.V394= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1287845081, COSV52165309, COSV52165333; called by muse, mutect2, varscan2
- ZNF57 | c.1221C>T p.F407= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV60984827; called by muse, mutect2, varscan2
- ZNF808 | c.2064C>T p.F688= | Silent (SNP) | VAF 43/202 reads (21%) | catalogued as rs770686298, COSV63120644; called by muse, mutect2, varscan2
- ZSWIM5 | c.2334C>T p.S778= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV62737226; called by muse, mutect2, varscan2
- ADAM28 | c.-2G>A | 5'UTR (SNP) | VAF 30/96 reads (31%) | catalogued as rs774374373, COSV99739954; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918840 C>T | 5'Flank (SNP) | VAF 8/15 reads (53%) | catalogued as rs1403195329, COSV62703986; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918841 C>T | 5'Flank (SNP) | VAF 8/14 reads (57%) | catalogued as rs1386111456; called by muse, mutect2, varscan2
- C3P1 | n.3295G>A | RNA (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- KALRN | c.4929+22029C>T | Intron (SNP) | VAF 29/59 reads (49%) | catalogued as rs1472600108; called by muse, mutect2, varscan2
- KIR3DX1 | n.493C>T | RNA (SNP) | VAF 18/37 reads (49%) | catalogued as COSV55599112; called by muse, mutect2, varscan2
- LRP5L | n.500C>T | RNA (SNP) | VAF 29/49 reads (59%) | catalogued as rs200406094; called by muse, mutect2, varscan2
- MDS2 | n.89C>G | RNA (SNP) | VAF 2/9 reads (22%) | called by muse, mutect2
- MIR1-1HG-AS1 | n.770C>T | RNA (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- NACA | c.71-3112C>T | Intron (SNP) | VAF 32/108 reads (30%) | catalogued as rs746002980; called by muse, varscan2
- RAB26 | chr16:2155080 G>A | 3'Flank (SNP) | VAF 8/25 reads (32%) | catalogued as rs374288060; called by muse, mutect2, varscan2
